Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RN, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RN-01A (Primary Tumor).

[page 1 of 2]
Nature of material: Brain

Received on:

Macroscopy:

Multiple irregular pieces of brown-gray and soft tissue, measuring together 2.6 x 2.0 x 1.0 cm.

Microscopy:

The histological sections exhibit malignancy with moderate cellularity composed of cells with glial phenotype arranged in matrix something fibrillar. The neoplastic cells exhibit moderate atypia and pleomorphism. Have oval nuclei, evenly distributed chromatin and inconspicuous nucleoli. Many cells show a clear cytoplasm. In areas of high cellularity, cells tend to have more irregular nuclei and dense chromatin. It is note the multiple foci of dystrophic calcification in middle of the lesion. The vasculature consists of abundant and branched capillaries. Some vessels show foci of endothelial proliferation. We observed occasional mitotic figures, including atypical figures, especially in areas of high cell density. There are no areas of necrosis.

Diagnosis:

Biopsy product of lesion in the left insula:

- Anaplastic oligodendroglioma (grade III-WHO, 2007). ICD-O 9451/3 - see note.

NOTES:

- The presence of heterogeneous areas in the lesion raised the possibility of progression from low-grade oligodendroglioma (grade II) to anaplastic oligodendroglioma (grade III).

PROFESSIONAL PARTICIPANTS OF REPORT

CELLF ICD-O-3

path Oligodendroglioma, grade II 9450/3

path Oligodendroglioma, grade III 9451/3

CELLF Site Brain, supratentorial NOS C71.0

path Brain, insular C71.0

path 10/4/13

Per TSS, dx discrepancy from
States TCGA tumor to be grade II
(not grade III). BCP

Reviewer Initials	BT	Reviewed: 8/12/2013

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Brain lower grade glioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report Oligodendroglioma grade III Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF Oligodendroglioma grade II Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form wrote in TCGA Pathologic Diagnosis Discrepancy Form: " I was not involved in the initial diagnosis. In my opinion there is criteria for grade III in this tumor. I reviewed all slides". Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file ef3d721f-f944-45bd-88bc-3106fecd0958 (TCGA-TQ-A7RN.87A66ECE-00EE-4D45-83BF-1A9F26D1DA8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).